Somatic mutation profile of tumor specimen TCGA-DK-A6B1-01A (aliquot TCGA-DK-A6B1-01A-12D-A30E-08) from TCGA case TCGA-DK-A6B1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 67.4 years (24,607 days).
Specimen TCGA-DK-A6B1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb310fee-c9c0-4254-9bea-040e2e675af6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6B1-10A (Blood Derived Normal), aliquot TCGA-DK-A6B1-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02e52025-7568-4d84-9f1d-9a156e67d709

The open-access MAF lists 155 somatic variants for this specimen: 117 protein-altering or splice-affecting, 31 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 31, Nonsense Mutation 7, Frame Shift Del 6, Intron 5, Splice Site 5, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778104039, COSV57252908; called by muse, mutect2
- ERBB3 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57252926, COSV99916817; called by muse, mutect2, varscan2
- RPS6KA4 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs746466314, COSV53702062; called by muse, mutect2, varscan2
- AC008397.2 | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53206818; called by muse, mutect2, varscan2
- ADGRG4 | c.9206-1G>C p.X3069_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV54955497; called by muse, mutect2, varscan2
- ADH1A | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52924896; called by muse, mutect2, varscan2
- ADH1A | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52924904; called by muse, mutect2, varscan2
- AKAP6 | c.3956T>C p.V1319A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99798709; called by muse, mutect2
- ANKRD13C | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs761816981, COSV52031716; called by muse, mutect2, varscan2
- ANO5 | c.1753T>G p.Y585D | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61084766; called by muse, mutect2, varscan2
- ASXL2 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99710349; called by muse, mutect2, varscan2
- BRINP3 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66511641, COSV66523421; called by muse, mutect2, varscan2
- BSN | c.8504G>A p.R2835H | Missense Mutation (SNP) | VAF 80/123 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs147846190; called by muse, mutect2, varscan2
- BZW1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV100729825; called by muse, mutect2, varscan2
- CACNA1B | c.5738G>A p.R1913Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.32); catalogued as rs779631598, COSV53125232; called by muse, mutect2, varscan2
- CALD1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775853439, COSV62647217; called by muse, mutect2, varscan2
- CD163 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63132050; called by muse, mutect2, varscan2
- CEP112 | c.1547T>G p.L516* | Nonsense Mutation (SNP) | VAF 61/106 reads (58%) | catalogued as COSV101210555; called by muse, mutect2, varscan2
- COPB2 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100300499; called by muse, mutect2, varscan2
- DLGAP1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as COSV59801986; called by muse, varscan2
- DLGAP1 | c.1761C>A p.S587R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59802046; called by muse, varscan2
- DNAAF4 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs552975153, COSV58248775; called by muse, mutect2, varscan2
- EFTUD2 | c.1764C>G p.I588M | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV68183010; called by muse, mutect2, varscan2
- EFTUD2 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV68183015; called by muse, mutect2, varscan2
- ESR1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52787427, COSV52790229; called by muse, mutect2, varscan2
- FAM13B | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV50366121; called by muse, mutect2, varscan2
- FASTK | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV99879561; called by muse, mutect2
- FBXW2 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV61596942; called by muse, mutect2, varscan2
- GCM1 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52521736; called by muse, mutect2, varscan2
- GIMAP7 | c.147A>C p.K49N | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57959329; called by muse, mutect2
- GPR75 | c.242T>C p.F81S | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61827072; called by muse, mutect2, varscan2
- GRIN2A | c.1034del p.G345Afs*19 | Frame Shift Del (DEL) | VAF 291/448 reads (65%) | catalogued as COSV58029462; called by mutect2, pindel, varscan2
- GRSF1 | c.956T>C p.I319T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV54655261; called by muse, mutect2, varscan2
- GUCY2C | c.2068+1G>C p.X690_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | catalogued as COSV53789990; called by muse, mutect2, varscan2
- HEATR5B | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV51850823, COSV51852479; called by muse, mutect2, varscan2
- HSPA4L | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99612602; called by muse, mutect2, varscan2
- HUS1B | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV57864755; called by muse, mutect2
- IQCK | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57522917; called by muse, mutect2, varscan2
- IQGAP1 | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV99184874; called by muse, mutect2, varscan2
- ITCH | c.993-1G>C p.X331_splice (on ENST00000262650 / NM_001257137.3; = p.X290_splice on NM_031483.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV52931693; called by muse, mutect2, varscan2
- ITGB8 | c.1720T>A p.C574S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56008209; called by muse, mutect2, varscan2
- KCNH3 | c.2758C>T p.R920W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs199565947, COSV57790893; called by mutect2, varscan2
- KCNT1 | c.2938G>C p.D980H (on ENST00000488444; = p.D999H on NM_020822.3) | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53701171; called by muse, varscan2
- KIAA1109 | c.9218T>C p.I3073T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV52672080; called by muse, mutect2, varscan2
- KIFC3 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs782599223, COSV101109098; called by muse, mutect2, varscan2
- KPNA2 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV57857526; called by muse, mutect2, varscan2
- LGALS13 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.587); catalogued as COSV55679902, COSV55680227; called by muse, mutect2, varscan2
- LMTK2 | c.2987C>G p.T996S | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51995355; called by muse, mutect2, varscan2
- LMX1B | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62739504; called by muse, mutect2, varscan2
- LRRK2 | c.7162G>A p.D2388N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV54152665; called by muse, mutect2
- LTN1 | c.2136G>T p.W712C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV63733743; called by muse, mutect2, varscan2
- LTN1 | c.2135G>C p.W712S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV63733746; called by muse, mutect2, varscan2
- MAP3K12 | c.2495C>G p.S832C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99912984; called by muse, mutect2
- MEF2A | c.583C>T p.Q195* (on ENST00000557942 / NM_001319206.2; = p.Q197* on NM_005587.4 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/190 reads (21%) | catalogued as COSV100573588, COSV57533538; called by muse, mutect2, varscan2
- MEPE | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs778403716, COSV63072688; called by muse, mutect2, varscan2
- NFATC2 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV65353231; called by muse, mutect2, varscan2
- NKG7 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765079634, COSV52467451; called by muse, mutect2, varscan2
- NPSR1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.079); catalogued as COSV100706676, COSV62200082; called by muse, mutect2, varscan2
- NUP188 | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV65362006; called by muse, mutect2, varscan2
- OPA1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV62480765; called by muse, mutect2, varscan2
- ORC5 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV52398479; called by muse, mutect2, varscan2
- OTUD5 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV99331617; called by muse, mutect2, varscan2
- PCBP4 | c.1186G>A p.E396K (on ENST00000322099 / NM_033010.2; = p.E353K on NM_020418.4) | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV59054550; called by muse, mutect2, varscan2
- PDGFD | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV56377446; called by muse, mutect2, varscan2
- PLXNA4 | c.2408A>G p.K803R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.464); catalogued as COSV100322697; called by muse, mutect2
- PNLDC1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs145458684, COSV99277898; called by muse, mutect2, varscan2
- POLA2 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV55483073; called by muse, mutect2, varscan2
- POU4F2 | c.110C>G p.S37W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as COSV55584183; called by muse, mutect2, varscan2
- PPP2R2C | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV58672381; called by muse, mutect2, varscan2
- PRKRA | c.809A>T p.Y270F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV57868694; called by muse, mutect2
- RHCG | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51515886; called by muse, mutect2, varscan2
- ROCK2 | c.4085C>G p.S1362C | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59956950; called by muse, mutect2, varscan2
- RPS6KA6 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV53115942, COSV53119531; called by muse, mutect2, varscan2
- SDK1 | c.2279+1G>A p.X760_splice | Splice Site (SNP) | VAF 26/35 reads (74%) | catalogued as COSV67367844; called by muse, mutect2, varscan2
- SETX | c.6337G>C p.D2113H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56384646; called by muse, mutect2, varscan2
- SLC45A2 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV56871668; called by muse, mutect2, varscan2
- SLFN12 | c.654T>G p.I218M | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV59225846; called by muse, mutect2, varscan2
- SPATA31A1 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1298405601; called by mutect2, varscan2
- SPATS1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55823148; called by muse, mutect2, varscan2
- SPEG | c.3687G>C p.Q1229H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56668373; called by muse, mutect2, varscan2
- STK32B | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51484622; called by muse, mutect2, varscan2
- SYT2 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66141968; called by muse, mutect2, varscan2
- TAFA5 | c.146C>G p.T49S (on ENST00000402357 / NM_001082967.3; = p.T42S on NM_015381.7) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as COSV60978072; called by muse, mutect2, varscan2
- TARS1 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as COSV54309090; called by muse, mutect2, varscan2
- TCFL5 | c.1173G>C p.Q391H | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV53895945, COSV99415839; called by muse, mutect2, varscan2
- TCTEX1D1 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV51075191; called by muse, mutect2
- THEG | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61073596, COSV61073818; called by muse, mutect2, varscan2
- TIMD4 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as rs369567558; called by muse, mutect2, varscan2
- TMOD4 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.596); catalogued as COSV54860593; called by muse, mutect2, varscan2
- TP53BP2 | c.3289G>C p.D1097H (on ENST00000343537 / NM_001031685.3; = p.D968H on NM_005426.2) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59066077, COSV59068353; called by muse, mutect2, varscan2
- TPCN1 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV59235170; called by muse, mutect2, varscan2
- TRAF5 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV54822468; called by muse, mutect2, varscan2
- TRIM28 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV53400066; called by muse, mutect2, varscan2
- TRIM46 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 82/119 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV58113725; called by muse, mutect2, varscan2
- TRMT6 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544190283, COSV52543210; called by muse, mutect2, varscan2
- TSTD2 | c.741_757del p.G248Rfs*8 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as COSV57845755; called by mutect2, pindel, varscan2
- USH2A | c.5992C>T p.R1998C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as rs777886737, COSV100233651, COSV56366217; called by muse, mutect2, varscan2
- UTRN | c.6727G>T p.V2243L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV62334900; called by muse, mutect2, varscan2
- WARS1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs758076089, COSV59925399; called by muse, mutect2, varscan2
- WHAMM | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV54496419; called by muse, mutect2, varscan2
- ZBTB4 | c.2393C>G p.P798R | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV60140162; called by muse, mutect2, varscan2
- ZNF365 | c.697A>T p.R233W | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV67925454; called by muse, mutect2, varscan2
- ZNF518A | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100283359; called by muse, mutect2, varscan2
- ZNF548 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV60240917; called by muse, mutect2, varscan2
- ZNF627 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV63142186; called by muse, mutect2, varscan2
- ZNF627 | c.968G>T p.R323I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV63142191, COSV63142977; called by muse, mutect2, varscan2
- ZNF638 | c.3976A>G p.I1326V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52486854; called by muse, mutect2, varscan2
- ZNF91 | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV56084200; called by muse, mutect2, varscan2
- ZZEF1 | c.7745A>T p.Q2582L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67557372; called by muse, mutect2, varscan2
- CAMK1 | c.521_522del p.V174Afs*14 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | called by pindel, varscan2
- CEP192 | c.5935_5936del p.E1979Tfs*11 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- EPHA3 | c.1594+3_1594+4del p.X532_splice | Splice Site (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- NCOA4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NID2 | c.1204_1205del p.D402Ffs*39 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by pindel, varscan2
- RPL17-C18orf32 | c.167_168del p.Q56Lfs*33 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel, varscan2
- TNFRSF10C | c.106dup p.Q36Pfs*24 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- VN1R5 | c.169A>C p.I57L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ADCY10 | c.3480C>T p.L1160= | Silent (SNP) | VAF 13/318 reads (4%) | catalogued as COSV63240703; called by muse, mutect2
- ARSI | c.873C>T p.V291= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV60817348; called by muse, mutect2, varscan2
- C10orf90 | c.456C>T p.R152= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV52949277; called by muse, mutect2, varscan2
- C1QTNF7 | c.684T>C p.H228= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as COSV54852434; called by muse, mutect2, varscan2
- CDK18 | c.762T>C p.S254= (on ENST00000506784 / NM_212503.3; = p.S224= on NM_002596.4) | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as COSV63727414; called by muse, mutect2
- CHCHD1 | c.63G>A p.L21= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV65708123; called by muse, mutect2, varscan2
- CLDN14 | c.372C>G p.L124= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV59773643, COSV59776987; called by muse, mutect2, varscan2
- EFHC1 | c.1557C>T p.N519= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs773385237, COSV64135593; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- HSPA2 | c.375C>T p.L125= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV55969583; called by muse, mutect2, varscan2
- KCNA3 | c.543C>T p.S181= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV63901534; called by muse, mutect2, varscan2
- MFSD5 | c.330C>T p.L110= | Silent (SNP) | VAF 116/394 reads (29%) | catalogued as rs1387102849, COSV61565510; called by muse, mutect2, varscan2
- MUC2 | c.2169C>T p.F723= | Silent (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- MYO5A | c.3165T>C p.T1055= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV62559998; called by muse, mutect2, varscan2
- PAPPA | c.1975C>T p.L659= | Silent (SNP) | VAF 86/156 reads (55%) | catalogued as COSV60282783; called by muse, mutect2, varscan2
- PATJ | c.4173C>T p.F1391= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as rs558975401, COSV56249341; called by muse, mutect2, varscan2
- PCDHGB2 | c.24C>T p.C8= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV53943899; called by muse, mutect2, varscan2
- PPP1R3A | c.564C>T p.F188= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs1258569686, COSV52881985; called by muse, mutect2, varscan2
- PRKAG3 | c.1311C>T p.H437= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs201448081, COSV52101728; called by muse, varscan2
- RRN3 | c.1854C>T p.T618= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs373853014; called by muse, mutect2, varscan2
- SMAD6 | c.1323C>T p.F441= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1425838706, COSV56594546; called by muse, mutect2, varscan2
- SMPD3 | c.1818C>T p.I606= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs773382881, COSV54712107; called by muse, mutect2, varscan2
- SUPT7L | c.504C>T p.H168= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs770037914, COSV61822851; called by muse, mutect2, varscan2
- TAS2R46 | c.306C>T p.L102= | Silent (SNP) | VAF 78/156 reads (50%) | catalogued as rs1012865620, COSV67855627; called by muse, varscan2
- TENM3 | c.108C>A p.P36= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV69307286; called by muse, mutect2, varscan2
- TM9SF4 | c.1533C>T p.F511= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs770916128, COSV54105271; called by muse, mutect2, varscan2
- TRAV30 | c.195C>T p.F65= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- UGT2B17 | c.1374G>A p.L458= | Silent (SNP) | VAF 100/222 reads (45%) | catalogued as rs1300740842, COSV58501423; called by muse, mutect2, varscan2
- UNC119 | c.447C>T p.F149= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as COSV56378988; called by muse, mutect2, varscan2
- UTRN | c.6726G>T p.L2242= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV62334889; called by muse, mutect2, varscan2
- ZNF135 | c.774C>A p.T258= (on ENST00000313434 / NM_001289401.2; = p.T270= on NM_003436.4) | Silent (SNP) | VAF 50/249 reads (20%) | catalogued as COSV57881968; called by muse, mutect2, varscan2
- ZNF461 | c.1368C>G p.L456= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV64452884, COSV64455033; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503413 del CTTTAAATAATTTCTTAAAAGCCTCTAAAGTGA | 5'Flank (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- ERCC6 | c.1397+7756C>T | Intron (SNP) | VAF 11/29 reads (38%) | catalogued as COSV63389962; called by muse, mutect2, varscan2
- HLA-L | n.1002T>C | RNA (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- KALRN | c.4929+22006G>A | Intron (SNP) | VAF 37/130 reads (28%) | catalogued as rs1271817050, COSV53762954; called by muse, mutect2, varscan2
- NAE1 | c.54-1235G>A | Intron (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99322972; called by muse, mutect2, varscan2
- PCBP4 | c.388-41T>A | Intron (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100436918; called by muse, mutect2
- UGGT2 | c.1031+1053G>C | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV65025323; called by muse, mutect2, varscan2
